Somatic mutation profile of tumor specimen C3L-03491-54 (aliquot CPT0201160002) from CPTAC case C3L-03491, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 55.9 years (20,405 days).
Specimen C3L-03491-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c19a93ed-7765-41e6-876f-2c036a64bbf7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03491-50 (Buccal Cell Normal), aliquot CPT0201260002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f4b16384-3f40-4bee-accf-f4fb82134031

The open-access MAF lists 1 somatic variant for this specimen: 1 silent.
By variant classification: Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PDE1C | c.306C>A p.V102= | Silent (SNP) | VAF 10/282 reads (4%) | called by muse, mutect2
